Somatic mutation profile of tumor specimen TCGA-HT-7606-01A (aliquot TCGA-HT-7606-01A-11D-2086-08) from TCGA case TCGA-HT-7606, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 30.8 years (11,233 days).
Specimen TCGA-HT-7606-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3eccdaf0-ccd5-4d4f-ba6d-17f527f52ff6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7606-10A (Blood Derived Normal), aliquot TCGA-HT-7606-10A-01D-2086-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4442e1b-2620-4def-a6f0-15139c401a89

The open-access MAF lists 34 somatic variants for this specimen: 22 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 19, Silent 12, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 32/83 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 8/8 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASPM | c.3515C>T p.T1172M | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs201067420, COSV54128368; called by muse, mutect2, varscan2
- CFHR5 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.123); catalogued as COSV56826382; called by muse, mutect2, varscan2
- DDX31 | c.1324A>G p.S442G | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.2); catalogued as COSV60138691; called by muse, mutect2, varscan2
- GSPT2 | c.1726G>A p.V576M | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61214877; called by muse, mutect2, varscan2
- HELZ | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.475); catalogued as rs374896136, COSV100699070; called by muse, mutect2, varscan2
- JPH1 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60613752; called by muse, mutect2, varscan2
- KCNJ8 | c.299A>G p.D100G | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV53717772; called by muse, mutect2, varscan2
- NUDCD1 | c.1082T>G p.V361G | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV53459525; called by muse, mutect2, varscan2
- PCDH18 | c.1235A>G p.E412G | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61271198, COSV61271269; called by muse, mutect2, varscan2
- PCDHA11 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 141/308 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as COSV56489775; called by muse, mutect2, varscan2
- PLEKHA5 | c.2177A>C p.E726A | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV54709796; called by muse, mutect2, varscan2
- RTL3 | c.994C>A p.L332I | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV58185357; called by muse, mutect2, varscan2
- SIPA1 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs945236130, COSV63139591; called by muse, mutect2, varscan2
- SLC25A1 | c.646A>C p.K216Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.292); catalogued as COSV53206539; called by muse, mutect2, varscan2
- SMARCA4 | c.2650C>A p.H884N | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60804933, COSV60805174; called by muse, mutect2, varscan2
- ZNF138 | c.747A>C p.K249N (on ENST00000307355 / NM_001367572.1; = p.K223N on NM_006524.4) | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.362); catalogued as COSV56467038, COSV56468029; called by muse, mutect2, varscan2
- GAS2L2 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- POLR2B | c.3102_3131del p.R1035_G1044del | In Frame Del (DEL) | VAF 13/96 reads (14%) | called by mutect2, pindel
- PTEN | c.136_143del p.Y46Qfs*3 | Frame Shift Del (DEL) | VAF 14/31 reads (45%) | called by mutect2, pindel, varscan2
- RBM41 | c.607del p.E203Kfs*6 | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | called by mutect2, pindel, varscan2
- ANK3 | c.1674A>G p.L558= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV55075162; called by muse, mutect2, varscan2
- DUSP22 | c.441G>T p.R147= | Silent (SNP) | VAF 24/117 reads (21%) | catalogued as COSV60529944; called by muse, mutect2, varscan2
- EPS15L1 | c.2373G>A p.P791= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs754239491, COSV50173216; called by muse, mutect2, varscan2
- FGR | c.648C>T p.F216= | Silent (SNP) | VAF 63/191 reads (33%) | catalogued as COSV64969707, COSV64969725; called by muse, mutect2, varscan2
- FIGNL1 | c.1452A>G p.A484= | Silent (SNP) | VAF 50/126 reads (40%) | catalogued as COSV63553936; called by muse, mutect2, varscan2
- LRRC8D | c.1449C>T p.P483= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs370858889; called by muse, mutect2, varscan2
- LRRK1 | c.3225A>G p.T1075= | Silent (SNP) | VAF 55/88 reads (63%) | catalogued as COSV52623141; called by muse, mutect2, varscan2
- OR2AG2 | c.600C>T p.Y200= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs1459957291, COSV58454864; called by muse, mutect2, varscan2
- TENM1 | c.5637G>A p.G1879= | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as COSV64439804; called by muse, mutect2, varscan2
- VIL1 | c.1020C>T p.A340= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs778555180, COSV50294061; called by muse, mutect2, varscan2
- ZFP37 | c.291A>G p.R97= | Silent (SNP) | VAF 25/32 reads (78%) | catalogued as rs768837210, COSV65288122; called by muse, mutect2, varscan2
- ZSCAN20 | c.2481T>G p.P827= | Silent (SNP) | VAF 97/236 reads (41%) | catalogued as COSV63684050; called by muse, mutect2, varscan2
